Somatic mutation profile of tumor specimen C3L-07080-02 (aliquot CPT0412160009) from CPTAC case C3L-07080, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 74.9 years (27,373 days).
Specimen C3L-07080-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4141df3a-1771-43fe-9ff5-1280753ecf65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07080-31 (Blood Derived Normal), aliquot CPT0412330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a16cef1-4094-4727-b86e-91b0d1100173

The open-access MAF lists 1,828 somatic variants for this specimen: 1,348 protein-altering or splice-affecting, 424 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,024, Silent 424, Frame Shift Del 182, Frame Shift Ins 61, Nonsense Mutation 45, Intron 30, In Frame Del 14, Splice Region 13, 3'UTR 8, 5'UTR 5, Splice Site 5, 5'Flank 5.

Variants (750 of 1,828; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATL1 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as rs119476046, CM013290, COSV63296065; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRCA1 | c.1016del p.K339Rfs*2 | Frame Shift Del (DEL) | VAF 30/255 reads (12%) | catalogued as rs80357569, CD951606; ClinVar: pathogenic; called by pindel, varscan2
- CHRNB1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs199875082, CM078176; ClinVar: uncertain significance / pathogenic; called by muse, mutect2
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 55/355 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 45/363 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LIFR | c.1578del p.K526Nfs*4 | Frame Shift Del (DEL) | VAF 19/188 reads (10%) | catalogued as rs1554020702; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 54/305 reads (18%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 16/152 reads (11%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 36/280 reads (13%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, varscan2
- NDE1 | c.733del p.L245Sfs*26 (on ENST00000577101; = p.L245Sfs*113 on NM_017668.3) | Frame Shift Del (DEL) | VAF 45/423 reads (11%) | catalogued as rs749768828; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NIPBL | c.1885C>T p.R629* | Nonsense Mutation (SNP) | VAF 21/299 reads (7%) | catalogued as rs587783892, CM051563; ClinVar: pathogenic; called by muse, mutect2
- RRAS2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs782457908, COSV56329532; ClinVar: pathogenic; called by muse, mutect2
- SMARCB1 | c.958C>T p.R320C (on ENST00000263121; = p.R366C on NM_003073.5) | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs886039520, CM1311955, COSV51954443; ClinVar: pathogenic; called by muse, mutect2
- ABHD16B | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 50/652 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as rs1458122994; called by muse, mutect2
- ABL1 | c.2033del p.G678Afs*16 | Frame Shift Del (DEL) | VAF 64/508 reads (13%) | catalogued as COSV100583845, COSV59326584; called by mutect2, pindel, varscan2
- AC138647.1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 66/562 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); catalogued as rs534096708; called by muse, mutect2, varscan2
- ACAP3 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 60/568 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs776871542, COSV57639729; called by muse, mutect2, varscan2
- ACCSL | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs772094369, COSV66581979; called by muse, mutect2, varscan2
- ACE2 | c.1082G>A p.C361Y | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99383260; called by muse, mutect2, varscan2
- ACKR4 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 52/524 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1398393923, COSV51442163; called by muse, mutect2, varscan2
- ACLY | c.2743C>T p.R915* | Nonsense Mutation (SNP) | VAF 56/356 reads (16%) | catalogued as rs1555625209, COSV61252892; called by muse, mutect2, varscan2
- ACOX2 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756958019; called by muse, mutect2, varscan2
- ACRBP | c.360_361del p.R120Sfs*13 | Frame Shift Del (DEL) | VAF 20/176 reads (11%) | catalogued as rs772890592; called by pindel, varscan2
- ACSM6 | c.1381G>A p.G461S | Missense Mutation (SNP) | VAF 38/391 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs530789365; called by muse, mutect2
- ACSS2 | c.662A>G p.E221G | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs763870941, COSV99489469; called by muse, mutect2, varscan2
- ACTB | c.719A>G p.Y240C | Missense Mutation (SNP) | VAF 27/389 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV59319508; called by muse, mutect2
- ADAMTS6 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1287447624; called by muse, mutect2, varscan2
- ADAMTS7 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 68/480 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs757294838; called by muse, mutect2
- ADCY6 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 39/354 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433790319, COSV100326993; called by muse, mutect2, varscan2
- ADCY8 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 60/621 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs780633874; called by muse, mutect2
- ADGRB1 | c.3508G>A p.A1170T | Missense Mutation (SNP) | VAF 40/363 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1164121347, COSV60098368; called by muse, mutect2, varscan2
- AEN | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 35/334 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376478935; called by muse, mutect2, varscan2
- AFAP1L2 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 49/373 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as rs772660863; called by muse, mutect2, varscan2
- AGPAT3 | c.1124A>G p.K375R | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.127); catalogued as COSV52371749, COSV52372777; called by muse, mutect2, varscan2
- AHCY | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); catalogued as rs1490934421, COSV99028099; called by muse, varscan2
- AHCYL2 | c.1598C>T p.T533I | Missense Mutation (SNP) | VAF 39/292 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs1238458429; called by muse, mutect2, varscan2
- AKAP1 | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 31/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs914781524, COSV100532843; called by muse, mutect2
- AKAP8L | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101275878; called by muse, mutect2
- ALDH1A3 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs370671214; called by muse, varscan2
- ALDH5A1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as rs1222413080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.3685G>A p.V1229M | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.601); catalogued as rs776228721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKAL1 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 17/441 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as rs1029734290; called by muse, mutect2
- ALKBH4 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 59/485 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.733); catalogued as rs548994210; called by muse, mutect2, varscan2
- AMER2 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 67/576 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.216); catalogued as rs1393438081; called by muse, mutect2, varscan2
- ANGPT2 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs936575985, COSV57335765; called by muse, mutect2, varscan2
- ANKRD36B | c.3224G>A p.R1075H | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs748493958; called by muse, mutect2, varscan2
- ANKRD50 | c.1586G>T p.R529L | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs183969638, COSV72385979; called by muse, mutect2, varscan2
- ANKRD63 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 42/563 reads (7%) | SIFT deleterious (0.01); catalogued as rs1485315250; called by muse, mutect2
- ANXA7 | c.1250G>A p.R417H (on ENST00000372919 / NM_001320880.2; = p.R395H on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs568535721, COSV100873447; called by muse, mutect2, varscan2
- AOC1 | c.1942G>A p.V648M | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs561950163, COSV62868800; called by muse, mutect2, varscan2
- AP4B1 | c.2156C>T p.T719M | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.225); catalogued as rs564093511, COSV56724254; called by muse, mutect2, varscan2
- APEH | c.36G>T p.E12D | Missense Mutation (SNP) | VAF 58/460 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV56518014; called by muse, mutect2, varscan2
- APOA5 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 59/422 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs751970941; called by muse, mutect2, varscan2
- APOBEC3C | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 39/371 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778936845; called by muse, mutect2, varscan2
- ARAP3 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as rs575984491; called by muse, mutect2
- ARF1 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.005); catalogued as COSV55254115; called by muse, mutect2
- ARFGEF3 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 75/445 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.163); catalogued as rs370299291; called by muse, mutect2, varscan2
- ARHGAP23 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 44/628 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1272686732; called by muse, mutect2
- ARHGAP36 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.956); catalogued as COSV99358021; called by muse, mutect2, varscan2
- ARHGEF33 | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 59/504 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as COSV67256156; called by muse, mutect2, varscan2
- ARHGEF4 | c.65T>C p.M22T | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs199809047; called by muse, mutect2, varscan2
- ARHGEF6 | c.1244T>C p.M415T | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV99032244; called by muse, mutect2, varscan2
- ARID1B | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.021); catalogued as rs753422144; called by muse, varscan2
- ARMC5 | c.2069G>A p.R690Q | Missense Mutation (SNP) | VAF 67/552 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs758434668, COSV51655699; called by muse, mutect2, varscan2
- ARPC3 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.41); catalogued as rs770613931; called by muse, mutect2, varscan2
- ARPP21 | c.345del p.E116Kfs*32 | Frame Shift Del (DEL) | VAF 26/252 reads (10%) | catalogued as rs1559620004; called by mutect2, pindel, varscan2
- ART1 | c.735del p.F246Lfs*6 | Frame Shift Del (DEL) | VAF 42/406 reads (10%) | catalogued as rs762428866, COSV99167258; called by mutect2, pindel, varscan2
- ASB14 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs766196189; called by muse, mutect2, varscan2
- ATG2B | c.6044C>T p.A2015V | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200638090, COSV55892219; called by muse, mutect2, varscan2
- ATG9B | c.1968dup p.H657Sfs*36 | Frame Shift Ins (INS) | VAF 45/357 reads (13%) | catalogued as rs759925498; called by mutect2, pindel, varscan2
- ATP8B4 | c.1530del p.F510Lfs*9 | Frame Shift Del (DEL) | VAF 36/350 reads (10%) | catalogued as COSV52716274; called by mutect2, pindel
- AUTS2 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as rs1454617445; called by muse, mutect2
- B4GALNT4 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 103/704 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1367460258; called by muse, mutect2, varscan2
- BAIAP2L2 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 45/344 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100207250; called by muse, mutect2, varscan2
- BANP | c.1126G>A p.A376T (on ENST00000286122; = p.A345T on NM_017869.4) | Missense Mutation (SNP) | VAF 58/466 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.829); catalogued as rs768066560; called by muse, mutect2, varscan2
- BAZ1B | c.1121C>T p.S374L | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs782044136, COSV100289995; called by muse, mutect2, varscan2
- BDP1 | c.5489G>T p.R1830M | Missense Mutation (SNP) | VAF 63/532 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62433950; called by muse, mutect2, varscan2
- BEST3 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 23/428 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1466171439, COSV56994732; called by muse, mutect2
- BHLHE40 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 50/377 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs753105254; called by muse, mutect2, varscan2
- BICD2 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 64/437 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100794093; called by muse, mutect2, varscan2
- BMP3 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 61/455 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.637); catalogued as rs750199975; called by muse, mutect2, varscan2
- BMP8B | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 29/333 reads (9%) | catalogued as rs144839101; called by muse, mutect2
- BROX | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.686); catalogued as rs759093572; called by muse, mutect2, varscan2
- BTBD16 | c.729dup p.T244Dfs*26 | Frame Shift Ins (INS) | VAF 50/385 reads (13%) | catalogued as rs774408792; called by mutect2, pindel, varscan2
- BUB3 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV64363991; called by muse, mutect2
- C11orf16 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 58/371 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs201086464; called by muse, mutect2, varscan2
- C1QB | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544508692, CM116184, COSV59245564; called by muse, varscan2
- C1orf122 | c.268del p.Q90Sfs*42 | Frame Shift Del (DEL) | VAF 32/382 reads (8%) | catalogued as rs747134922; called by mutect2, pindel
- C1orf158 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as rs757604143, COSV55346313, COSV55347418; called by muse, mutect2
- C3orf22 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 39/375 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs202039278, COSV100559560; called by muse, mutect2, varscan2
- C6orf132 | c.1838C>A p.P613H | Missense Mutation (SNP) | VAF 34/498 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1453309272, COSV59373032; called by muse, mutect2
- C6orf62 | c.510_512del p.V171del | In Frame Del (DEL) | VAF 40/317 reads (13%) | catalogued as rs1261411022; called by mutect2, pindel, varscan2
- C8A | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs530776774, COSV100776515; called by muse, varscan2
- CACNA1C | c.3985C>T p.R1329C | Missense Mutation (SNP) | VAF 52/379 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59753193; called by muse, mutect2, varscan2
- CACNA1G | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs542038781; called by muse, mutect2, varscan2
- CACNG6 | c.614C>T p.P205L (on ENST00000252729 / NM_145814.1; = p.P134L on NM_031897.2) | Missense Mutation (SNP) | VAF 52/441 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as rs751492357; called by muse, mutect2, varscan2
- CADPS | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781371846, COSV51904713; called by muse, mutect2, varscan2
- CAPSL | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 44/401 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.101); catalogued as rs781283312; called by muse, mutect2, varscan2
- CARMIL3 | c.3589G>A p.A1197T | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.985); catalogued as rs745477142, COSV57725246; called by muse, mutect2, varscan2
- CARMIL3 | c.4075C>T p.R1359W | Missense Mutation (SNP) | VAF 47/343 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); catalogued as rs139310553; called by muse, mutect2, varscan2
- CASKIN2 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 60/537 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs771609546; called by muse, mutect2, varscan2
- CATSPERD | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs1475011855, COSV67534362; called by muse, mutect2, varscan2
- CBFA2T3 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 58/401 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as rs146630443; called by muse, mutect2, varscan2
- CBL | c.478C>A p.H160N | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99877398; called by muse, mutect2, varscan2
- CBLN1 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54654258; called by muse, mutect2
- CC2D1B | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 57/370 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1431952512; called by muse, mutect2, varscan2
- CCDC166 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 58/580 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1262427244; called by muse, mutect2
- CCDC173 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 42/349 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as rs753205961, COSV69573579; called by muse, mutect2, varscan2
- CCDC80 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 48/431 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52814717; called by muse, mutect2, varscan2
- CCDC93 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767493504, COSV104407830; called by muse, varscan2
- CCNJL | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 35/418 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs748396775; called by muse, mutect2
- CCNT1 | c.2081G>A p.R694Q | Missense Mutation (SNP) | VAF 36/327 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.815); catalogued as rs763437613; called by muse, mutect2, varscan2
- CCR4 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs372152475; called by muse, varscan2
- CD247 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV100758347; called by muse, mutect2, varscan2
- CD2BP2 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 42/566 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs1417364105, COSV99977201; called by muse, mutect2
- CD53 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 40/388 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); catalogued as rs369006161, COSV54760274; called by muse, mutect2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 94/323 reads (29%) | catalogued as rs762805003; called by mutect2, pindel, varscan2
- CDC14B | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765807616, COSV55785345; called by muse, mutect2, varscan2
- CDC42BPA | c.5126del p.P1709Qfs*56 (on ENST00000334218 / NM_001366019.2; = p.P1696Qfs*56 on NM_003607.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 49/381 reads (13%) | catalogued as rs869029351; called by mutect2, pindel, varscan2
- CDH15 | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs747187785; called by muse, mutect2, varscan2
- CDK20 | c.607del p.L203Ffs*104 (on ENST00000325303 / NM_001039803.3; = p.L182Ffs*104 on NM_012119.4) | Frame Shift Del (DEL) | VAF 33/322 reads (10%) | catalogued as COSV100308153; called by mutect2, pindel, varscan2
- CDKL2 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 31/343 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs749292580, COSV56734164; called by muse, mutect2
- CEACAM1 | c.426G>A p.P142= | Splice Region (SNP) | VAF 31/317 reads (10%) | catalogued as rs756230191, COSV50725329; called by muse, mutect2
- CEP164 | c.3612C>A p.A1204= | Splice Region (SNP) | VAF 12/264 reads (5%) | catalogued as COSV99633605; called by muse, mutect2
- CEP192 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 26/267 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.08); catalogued as rs1418949527; called by muse, mutect2
- CFAP46 | c.5381G>A p.R1794H | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.36); catalogued as rs762105561; called by muse, mutect2, varscan2
- CHST13 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 60/420 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.892); catalogued as rs781562956; called by muse, mutect2, varscan2
- CKAP2 | c.1441_1443del p.I481del (on ENST00000378037 / NM_001098525.2; = p.I480del on NM_018204.5) | In Frame Del (DEL) | VAF 37/215 reads (17%) | catalogued as rs757796870; called by pindel, varscan2
- CLDN6 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 49/500 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs1455379665, COSV58511108; called by muse, mutect2
- CLK1 | c.432T>G p.D144E | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV58432514; called by muse, mutect2, varscan2
- CMYA5 | c.2675G>A p.R892Q | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs759695468, COSV71409125, COSV71409920; called by muse, mutect2, varscan2
- CNTN1 | c.2039G>A p.R680H | Missense Mutation (SNP) | VAF 41/307 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770506056, COSV61645121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN5 | c.3037del p.Y1013Ifs*20 | Frame Shift Del (DEL) | VAF 17/172 reads (10%) | catalogued as COSV54281203; called by mutect2, varscan2
- CNTNAP3 | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 25/591 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1427108514, COSV52665237; called by muse, mutect2
- CNTNAP5 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV70470944; called by muse, mutect2, varscan2
- COA7 | c.405G>T p.R135S | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); catalogued as COSV65299915; called by muse, mutect2
- COL18A1 | c.4524del p.V1509Wfs*157 (on ENST00000359759 / NM_130444.3; = p.V1274Wfs*157 on NM_030582.4) | Frame Shift Del (DEL) | VAF 27/231 reads (12%) | catalogued as rs1344008575; called by mutect2, pindel, varscan2
- COL18A1 | c.4585C>T p.R1529W (on ENST00000359759 / NM_130444.3; = p.R1294W on NM_030582.4) | Missense Mutation (SNP) | VAF 29/384 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs749258477; called by muse, mutect2
- COL23A1 | c.732C>T p.G244= | Splice Region (SNP) | VAF 44/456 reads (10%) | catalogued as rs1193637344, COSV66787362; called by muse, mutect2
- COL4A5 | c.4141C>A p.P1381T | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.527); catalogued as COSV100087106; called by muse, mutect2, varscan2
- COX11 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs775330426; called by muse, mutect2
- CPA4 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs138137136, COSV55982748; called by muse, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 27/216 reads (13%) | catalogued as rs1378599948; called by mutect2, varscan2
- CRIP2 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 31/384 reads (8%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.768); catalogued as rs1384988182; called by muse, mutect2
- CROCC | c.3509G>A p.R1170H | Missense Mutation (SNP) | VAF 64/598 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as rs762876230, COSV65011671; called by muse, mutect2
- CROCC | c.5185C>T p.R1729W | Missense Mutation (SNP) | VAF 59/541 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs763067795; called by muse, mutect2, varscan2
- CSF1R | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM154517; called by muse, mutect2
- CSMD1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs781692154, COSV68262082; called by muse, mutect2, varscan2
- CSPG4 | c.4718G>A p.R1573Q | Missense Mutation (SNP) | VAF 71/454 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs752045565; called by muse, mutect2, varscan2
- CST4 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 37/303 reads (12%) | catalogued as rs767756120; called by mutect2, pindel, varscan2
- CTDP1 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 90/539 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs1292042896; called by muse, mutect2, varscan2
- CUL7 | c.3605C>T p.A1202V | Missense Mutation (SNP) | VAF 79/334 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs762601845, COSV54815030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL9 | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 62/456 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs764024686; called by muse, mutect2, varscan2
- CUL9 | c.2162G>A p.R721H | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs79419808; called by muse, varscan2
- CWF19L2 | c.314del p.N105Tfs*32 | Frame Shift Del (DEL) | VAF 21/219 reads (10%) | catalogued as rs1389859233; called by mutect2, pindel
- CWH43 | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 59/392 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV99893238; called by muse, mutect2, varscan2
- CYP7B1 | c.392dup p.N131Kfs*3 | Frame Shift Ins (INS) | VAF 32/220 reads (15%) | catalogued as rs748480664; called by mutect2, varscan2
- DCAF12L2 | c.1281C>A p.F427L | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV63580877; called by muse, mutect2, varscan2
- DCAF12L2 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776609885, COSV100758723, COSV63580588; called by muse, mutect2, varscan2
- DCAF4 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 51/380 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750942030; called by muse, mutect2, varscan2
- DCLK3 | c.327del p.R110Gfs*69 | Frame Shift Del (DEL) | VAF 54/424 reads (13%) | catalogued as COSV101373865, COSV69362732; called by mutect2, pindel, varscan2
- DEFB114 | c.18T>A p.Y6* | Nonsense Mutation (SNP) | VAF 12/192 reads (6%) | catalogued as rs1399259570; called by muse, mutect2
- DENND2B | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 45/505 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.251); catalogued as rs1253775128, COSV58206334; called by muse, mutect2
- DGKB | c.907del p.R303Gfs*32 | Frame Shift Del (DEL) | VAF 38/307 reads (12%) | catalogued as COSV51768398; called by mutect2, pindel, varscan2
- DIP2A | c.2545G>A p.V849M | Missense Mutation (SNP) | VAF 30/408 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1367407880, COSV59482960; called by muse, mutect2
- DIP2B | c.3781G>T p.G1261C | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99999324; called by muse, mutect2, varscan2
- DLG4 | c.1262C>T p.A421V (on ENST00000399506 / NM_001321075.3; = p.A464V on NM_001365.4) | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs747653625; called by muse, mutect2, varscan2
- DMRTA2 | c.566A>C p.K189T | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.204); catalogued as rs1414738722; called by muse, mutect2, varscan2
- DMRTB1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 65/444 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV101008283; called by muse, mutect2, varscan2
- DNAH12 | c.2543G>A p.R848H (on ENST00000351747; = p.R871H on NM_001366028.2) | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1329216640; called by muse, mutect2, varscan2
- DNAH14 | c.10039C>T p.R3347* (on ENST00000445597; = p.R4355* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 44/287 reads (15%) | catalogued as rs773835192; called by muse, mutect2, varscan2
- DNAJC16 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761891997; called by muse, mutect2, varscan2
- DNHD1 | c.3100G>A p.E1034K | Missense Mutation (SNP) | VAF 32/313 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1264126515, COSV99600608; called by muse, mutect2, varscan2
- DOCK1 | c.3562A>G p.M1188V | Missense Mutation (SNP) | VAF 43/323 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV54748065; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 37/198 reads (19%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPEP1 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 44/366 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1043397364, COSV55358954; called by muse, mutect2, varscan2
- DPY19L2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 36/471 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.876); catalogued as rs1218448749; called by muse, mutect2
- DZIP1 | c.1493C>T p.S498L (on ENST00000347108; = p.S479L on NM_014934.5) | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs755679148, COSV61264204; called by muse, mutect2, varscan2
- EEFSEC | c.823A>G p.M275V | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1329775044; called by muse, mutect2
- EFNB3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 51/542 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs759236058, COSV56833542; called by muse, mutect2
- EFS | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 43/405 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs746796291; called by muse, mutect2, varscan2
- EHBP1L1 | c.3349G>A p.A1117T | Missense Mutation (SNP) | VAF 25/463 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as rs1432977098; called by muse, mutect2
- EIF4G3 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as rs760702730; called by muse, mutect2, varscan2
- ELK3 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 34/521 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV57385851; called by muse, mutect2
- ELMOD3 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 33/341 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770248019; called by muse, mutect2, varscan2
- ENTPD4 | c.1720G>C p.V574L | Missense Mutation (SNP) | VAF 25/495 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV100652667; called by muse, mutect2
- EPHA6 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 86/566 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs766646757; called by muse, mutect2, varscan2
- ERBIN | c.3398G>A p.S1133N | Missense Mutation (SNP) | VAF 42/272 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1298429393, COSV52326630; called by muse, mutect2, varscan2
- ERVV-2 | c.788del p.N263Ifs*11 | Frame Shift Del (DEL) | VAF 44/417 reads (11%) | catalogued as rs1462590370; called by mutect2, pindel, varscan2
- EYA1 | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 11/288 reads (4%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.264); catalogued as rs1164012590; called by muse, mutect2
- FAHD2B | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 29/259 reads (11%) | catalogued as COSV99738313; called by muse, mutect2, varscan2
- FAM122B | c.441_443del p.R148del (on ENST00000370790 / NM_001166599.3; = p.R149del on NM_145284.5) | In Frame Del (DEL) | VAF 17/106 reads (16%) | catalogued as rs777298062; called by mutect2, pindel, varscan2
- FAM131B | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 23/319 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775728202; called by muse, mutect2
- FAM170A | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 31/308 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs756219422; called by muse, mutect2, varscan2
- FAM205C | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as rs926882728; called by muse, varscan2
- FAM222A | c.1100T>C p.V367A | Missense Mutation (SNP) | VAF 48/575 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1230981917; called by muse, mutect2
- FAM222B | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 46/516 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs745952192; called by muse, mutect2
- FAT2 | c.11819C>T p.A3940V | Missense Mutation (SNP) | VAF 48/426 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.203); catalogued as rs746102336, COSV99942552; called by muse, mutect2, varscan2
- FAU | c.292A>G p.K98E | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1200469527; called by muse, mutect2, varscan2
- FBH1 | c.824G>A p.G275D (on ENST00000362091 / NM_178150.3; = p.G326D on NM_032807.4) | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.077); catalogued as COSV62981337; called by muse, mutect2
- FBRSL1 | c.1084A>G p.T362A | Missense Mutation (SNP) | VAF 52/734 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.41); catalogued as COSV99905583; called by muse, mutect2
- FBXL3 | c.876T>A p.Y292* | Nonsense Mutation (SNP) | VAF 21/265 reads (8%) | catalogued as COSV62918322; called by muse, mutect2
- FBXO21 | c.432del p.F144Lfs*9 | Frame Shift Del (DEL) | VAF 26/228 reads (11%) | catalogued as rs772635228; called by mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 13/114 reads (11%) | catalogued as rs768979093, COSV55110370; called by mutect2, varscan2
- FCMR | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.213); catalogued as rs760153308; called by muse, mutect2
- FGD1 | c.1259G>A p.G420D | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as rs746321535; called by muse, mutect2, varscan2
- FGD6 | c.3169G>A p.A1057T | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748031655; called by muse, mutect2, varscan2
- FGFRL1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 58/501 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs868506112; called by muse, mutect2, varscan2
- FKBP11 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368125183; called by muse, mutect2, varscan2
- FLYWCH1 | c.1725G>C p.E575D (on ENST00000253928 / NM_001308068.2; = p.E574D on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/406 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as rs756674310; called by muse, mutect2, varscan2
- FOXC2 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 29/498 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as CD021827; called by muse, mutect2
- FOXI2 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 58/454 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59094064, COSV59094789; called by muse, mutect2, varscan2
- FOXL3 | c.26A>G p.Y9C | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1332647498; called by muse, mutect2
- FRA10AC1 | c.900dup p.S301Ifs*7 | Frame Shift Ins (INS) | VAF 30/215 reads (14%) | catalogued as rs773062554; called by mutect2, pindel, varscan2
- FRMPD4 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66214237; called by muse, mutect2, varscan2
- FSCB | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.735); catalogued as rs763071301; called by muse, mutect2, varscan2
- FSD1 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.164); catalogued as rs771854680; called by muse, mutect2, varscan2
- FUT4 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 27/728 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.297); catalogued as rs986358079; called by muse, mutect2
- GABRR3 | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.062); catalogued as rs746111039; called by muse, mutect2, varscan2
- GAL3ST3 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 51/450 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1211070600; called by muse, mutect2, varscan2
- GALNT17 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 61/405 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs1469235772; called by muse, mutect2, varscan2
- GAS7 | c.1228C>T p.R410W (on ENST00000432992 / NM_201433.2; = p.R270W on NM_003644.3) | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1218326469; called by muse, varscan2
- GBX1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 60/583 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs745455115; called by muse, mutect2, varscan2
- GEMIN5 | c.3227C>T p.A1076V | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as rs780308853, COSV53564263; called by muse, mutect2
- GFOD1 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 41/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757177243, COSV64954512; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 18/165 reads (11%) | catalogued as rs750227570; called by mutect2, varscan2
- GJB3 | c.158G>A p.C53Y | Missense Mutation (SNP) | VAF 44/468 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100974022; called by muse, mutect2
- GLI2 | c.4142C>T p.A1381V (on ENST00000361492 / NM_001374353.1; = p.A1398V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/449 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV58051271; called by muse, mutect2, varscan2
- GNB3 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 58/402 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782249757, COSV51834464; called by muse, mutect2, varscan2
- GP6 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 73/538 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV59977190; called by muse, mutect2, varscan2
- GPR12 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 42/325 reads (13%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.01); catalogued as rs1410626956; called by muse, mutect2, varscan2
- GPR150 | c.556del p.D186Tfs*109 | Frame Shift Del (DEL) | VAF 36/373 reads (10%) | catalogued as rs1298303580; called by mutect2, pindel, varscan2
- GPR26 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 50/435 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52933349; called by muse, varscan2
- GPR61 | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 71/533 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV63983661; called by muse, mutect2, varscan2
- GPX3 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 41/321 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs1375876958, COSV59307576; called by muse, mutect2, varscan2
- GRAMD2B | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 34/335 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs756364725, COSV53506767; called by muse, mutect2, varscan2
- GREM2 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 50/321 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.418); catalogued as rs1337786253, COSV58954171; called by muse, mutect2, varscan2
- GRHL3 | c.1060G>A p.V354I (on ENST00000350501 / NM_198174.3; = p.V359I on NM_021180.3) | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs375437963; called by muse, varscan2
- GRIK5 | c.2748del p.S917Afs*? | Frame Shift Del (DEL) | VAF 51/420 reads (12%) | catalogued as rs1555870200; called by mutect2, pindel, varscan2
- GRIPAP1 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs782370453; called by muse, mutect2, varscan2
- GRK2 | c.1771C>T p.R591W | Missense Mutation (SNP) | VAF 37/434 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as rs1175693753; called by muse, mutect2
- GRM8 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs61751057; called by muse, mutect2, varscan2
- GSG1L | c.824G>A p.R275Q (on ENST00000447459 / NM_001109763.2; = p.R120Q on NM_144675.2) | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs376358621; called by muse, mutect2, varscan2
- GSX2 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 40/384 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100482549; called by muse, mutect2, varscan2
- GTF2I | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as rs145729076; called by muse, mutect2
- GYS1 | c.1325del p.P442Lfs*16 | Frame Shift Del (DEL) | VAF 28/322 reads (9%) | catalogued as rs751494565, COSV54405555; called by mutect2, pindel
- H2AC21 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 47/420 reads (11%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.041); catalogued as rs1553760144; called by muse, mutect2, varscan2
- HAS1 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.523); catalogued as rs750095254, COSV55786081; called by muse, mutect2, varscan2
- HDAC2 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64039456; called by muse, mutect2
- HDAC4 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 64/390 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs140596122, COSV61869055; called by muse, mutect2, varscan2
- HDAC7 | c.1396G>A p.G466R (on ENST00000427332; = p.G505R on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/513 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.111); catalogued as rs779938712; called by muse, mutect2, varscan2
- HEATR5A | c.3664C>T p.R1222* | Nonsense Mutation (SNP) | VAF 28/247 reads (11%) | catalogued as rs553912721, COSV66339471; called by muse, mutect2, varscan2
- HELZ2 | c.3620G>A p.R1207H (on ENST00000467148 / NM_001037335.2; = p.R638H on NM_033405.3) | Missense Mutation (SNP) | VAF 58/465 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as rs765790192; called by muse, mutect2, varscan2
- HEY2 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 76/547 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs763300749, COSV64239346; called by muse, mutect2, varscan2
- HFE | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 45/375 reads (12%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.654); catalogued as rs776741897, COSV58512665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HHIPL1 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.446); catalogued as rs1377483778; called by muse, mutect2
- HJV | c.557G>A p.R186H (on ENST00000336751 / NM_213653.4; = p.R73H on NM_145277.5) | Missense Mutation (SNP) | VAF 19/473 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs181376469, COSV60952711; called by muse, mutect2
- HLA-DQB2 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 42/285 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as rs1249792995, COSV101369982; called by muse, mutect2, varscan2
- HOXA2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 74/462 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as rs1205106631; called by muse, varscan2
- HOXA3 | c.904del p.Q302Rfs*74 | Frame Shift Del (DEL) | VAF 22/191 reads (12%) | catalogued as rs761726531; called by mutect2, pindel, varscan2
- HOXD12 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 65/402 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375056968; called by muse, mutect2, varscan2
- HPD | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 21/377 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.377); catalogued as COSV56642919; called by muse, mutect2
- HRNR | c.883G>T p.G295C | Missense Mutation (SNP) | VAF 51/559 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV64262057; called by muse, mutect2
- HSPA6 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 64/717 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs138613886; called by muse, mutect2
- HTRA4 | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 28/688 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as rs1307760394; called by muse, mutect2
- HYAL3 | c.1031C>A p.P344H | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.997); catalogued as COSV100269622; called by muse, mutect2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 26/200 reads (13%) | catalogued as rs747841314; called by mutect2, varscan2
- IFIT1 | c.1007del p.K336Sfs*9 | Frame Shift Del (DEL) | VAF 41/265 reads (15%) | catalogued as rs1202143274; called by mutect2, pindel, varscan2
- IFT172 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs984586780, COSV99562754; called by muse, mutect2
- IGHV1-24 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 36/344 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs370730270; called by muse, mutect2
- IGSF21 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 52/366 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs759984330, COSV52129658; called by muse, mutect2, varscan2
- IGSF3 | c.3089G>A p.R1030Q (on ENST00000369486 / NM_001007237.3; = p.R1050Q on NM_001542.4) | Missense Mutation (SNP) | VAF 62/416 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs1425177833; called by muse, varscan2
- IGSF9B | c.3351dup p.A1118Rfs*37 | Frame Shift Ins (INS) | VAF 61/640 reads (10%) | catalogued as rs769568183; called by mutect2, pindel
- IL2RG | c.359del p.K120Rfs*27 | Frame Shift Del (DEL) | VAF 54/204 reads (26%) | catalogued as CD159812; called by mutect2, varscan2
- IL6ST | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs755797298; called by muse, mutect2
- ILF3 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 39/509 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV99139307; called by muse, mutect2
- IMPDH1 | c.1436G>A p.R479Q (on ENST00000470772 / NM_001142573.2; = p.R565Q on NM_000883.4) | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.745); catalogued as COSV58315166; called by muse, mutect2, varscan2
- INPP4B | c.2134C>T p.R712* | Nonsense Mutation (SNP) | VAF 19/149 reads (13%) | catalogued as rs1364646936; called by muse, mutect2, varscan2
- INPP5B | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs746949498, COSV65958403; called by muse, mutect2, varscan2
- INSM1 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1238728326; called by muse, mutect2
- INSM2 | c.1605dup p.S536* | Frame Shift Ins (INS) | VAF 46/352 reads (13%) | catalogued as rs756928018; called by mutect2, varscan2
- INSR | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs181150880, COSV57163012; called by muse, mutect2, varscan2
- IRGC | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 45/398 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54986759, COSV99746674; called by muse, mutect2, varscan2
- IRS1 | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 103/467 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs896026781; called by muse, mutect2, varscan2
- IRS4 | c.1979A>G p.D660G | Missense Mutation (SNP) | VAF 54/253 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as COSV64533129, COSV64533795; called by muse, mutect2, varscan2
- IRX4 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 63/553 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV51471897; called by muse, mutect2, varscan2
- ISLR | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 40/523 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs765765449; called by muse, mutect2
- ITGA9 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 37/304 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs759719660, COSV53248471; called by muse, mutect2, varscan2
- ITGB7 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs750166096, COSV57240432; called by muse, mutect2, varscan2
- ITIH3 | c.1841C>A p.A614D | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV69649696; called by muse, mutect2
- ITPRIPL2 | c.883C>A p.R295S | Missense Mutation (SNP) | VAF 39/409 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as COSV67348182; called by muse, mutect2
- ITSN1 | c.4015G>A p.G1339R | Missense Mutation (SNP) | VAF 52/331 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1235619622; called by muse, mutect2, varscan2
- JAKMIP1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 75/575 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs1008936182, COSV51526406; called by muse, mutect2, varscan2
- JAKMIP1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 63/560 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV51528285; called by muse, mutect2, varscan2
- JCAD | c.838T>C p.C280R | Missense Mutation (SNP) | VAF 54/415 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1042936166; called by muse, mutect2, varscan2
- KAT14 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 58/369 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.65); catalogued as rs1223792906; called by muse, mutect2, varscan2
- KATNIP | c.4039C>T p.R1347W | Missense Mutation (SNP) | VAF 34/432 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181515149, COSV55192238; called by muse, mutect2
- KAZN | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 31/324 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1424730379; called by muse, mutect2, varscan2
- KCNH2 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 33/422 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs201268831, CM124760, CM139883; ClinVar: uncertain significance; called by muse, mutect2
- KCNJ12 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 64/920 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as rs376515121; called by muse, mutect2
- KCNK3 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 88/537 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV57192234; called by muse, mutect2, varscan2
- KCNQ2 | c.2273G>A p.G758D (on ENST00000359125 / NM_172107.4; = p.G730D on NM_004518.6) | Missense Mutation (SNP) | VAF 55/753 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.674); catalogued as rs1176031798; called by muse, mutect2
- KCNS2 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 28/539 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs972833387; called by muse, mutect2
- KCTD18 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 63/367 reads (17%) | catalogued as rs1224351673; called by muse, mutect2, varscan2
- KCTD8 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 66/494 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs905145774, COSV63598853; called by muse, mutect2, varscan2
- KDM5C | c.4594A>G p.T1532A | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV64765723; called by muse, mutect2
- KHSRP | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs765261230, COSV101231160; called by muse, mutect2, varscan2
- KIAA1109 | c.10765C>T p.R3589C | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1203575481, COSV52681632; called by muse, mutect2, varscan2
- KIAA1109 | c.13243G>A p.V4415I | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778904350; called by muse, mutect2
- KIAA1958 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1429552819, COSV61724821; called by muse, mutect2, varscan2
- KIDINS220 | c.4543C>T p.R1515C | Missense Mutation (SNP) | VAF 30/407 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.915); catalogued as rs760665628; called by muse, mutect2
- KIF13A | c.4048G>A p.V1350M | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs762633563, COSV99438956; called by muse, mutect2
- KIF16B | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 31/422 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs747897403, COSV61715933; called by muse, mutect2
- KIF26A | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 57/518 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs566897705, COSV100180718; called by muse, mutect2, varscan2
- KIF3C | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs772693472, COSV99268030; called by muse, mutect2, varscan2
- KLHDC7A | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 58/494 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV68769154; called by muse, mutect2, varscan2
- KLHDC8B | c.48del p.M17Cfs*59 | Frame Shift Del (DEL) | VAF 43/396 reads (11%) | catalogued as rs756907493; called by mutect2, pindel, varscan2
- KLHL14 | c.200dup p.L68Sfs*192 | Frame Shift Ins (INS) | VAF 76/641 reads (12%) | catalogued as rs1407187421; called by mutect2, pindel, varscan2
- KLHL3 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as rs555543412; called by muse, varscan2
- KLHL6 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 21/260 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs757613109, COSV100384379; called by muse, mutect2
- KLK10 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 77/494 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as rs746732310; called by muse, mutect2, varscan2
- KMT2B | c.4945G>A p.A1649T | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99719829; called by muse, mutect2, varscan2
- KPNA3 | c.1006T>A p.S336T | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs1566333261; called by muse, mutect2
- KRT1 | c.1603G>A p.G535R | Missense Mutation (SNP) | VAF 81/555 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs752221066, COSV52866725; called by muse, varscan2
- KRT23 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 59/528 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as rs754984346; called by muse, mutect2, varscan2
- KRT7 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 36/425 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1021750369, COSV57767706; called by muse, mutect2
- KRT71 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs780977717, COSV57289616; called by muse, mutect2, varscan2
- LACRT | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 53/405 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.519); catalogued as rs756932535; called by muse, mutect2, varscan2
- LAMA2 | c.6322C>T p.R2108W | Missense Mutation (SNP) | VAF 32/327 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs139824017; ClinVar: uncertain significance; called by muse, mutect2
- LAMA5 | c.3884C>T p.T1295M | Missense Mutation (SNP) | VAF 49/384 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1000734184; called by muse, mutect2, varscan2
- LAMP1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 37/304 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs756102656; called by muse, mutect2, varscan2
- LAPTM5 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1335245110, COSV53852390; called by muse, mutect2, varscan2
- LARP6 | c.1436G>A p.R479K | Missense Mutation (SNP) | VAF 48/326 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs1430629452, COSV54580734; called by muse, mutect2, varscan2
- LARP6 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 46/359 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs760004989; called by muse, mutect2, varscan2
- LDLR | c.2372C>T p.S791F | Missense Mutation (SNP) | VAF 36/424 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.073); catalogued as rs1368762538; called by muse, mutect2
- LEMD2 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 38/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs922219547; called by muse, mutect2, varscan2
- LGR5 | c.2357C>T p.S786F | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99878034; called by muse, mutect2
- LINS1 | c.1861del p.R621Gfs*7 | Frame Shift Del (DEL) | VAF 41/315 reads (13%) | catalogued as COSV59079528; called by mutect2, pindel, varscan2
- LMOD3 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 68/444 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.328); catalogued as rs774708945; called by muse, mutect2, varscan2
- LMTK3 | c.2175del p.A726Pfs*132 | Frame Shift Del (DEL) | VAF 32/220 reads (15%) | catalogued as rs1555901301; called by mutect2, varscan2
- LOXHD1 | c.5713G>A p.V1905M (on ENST00000642948; = p.V1843M on NM_144612.7) | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1406257799, COSV100192113; called by muse, mutect2, varscan2
- LRP5 | c.3312G>T p.E1104D | Missense Mutation (SNP) | VAF 18/561 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV99592103; called by muse, mutect2
- LRRC4C | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 30/397 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99074397; called by muse, mutect2
- LRRN4CL | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 96/550 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54016760; called by muse, mutect2, varscan2
- MACF1 | c.17729G>A p.R5910H (on ENST00000372915; = p.R3955H on NM_012090.5) | Missense Mutation (SNP) | VAF 33/296 reads (11%) | catalogued as rs1292252880; called by muse, mutect2, varscan2
- MACROD2 | c.875A>C p.E292A (on ENST00000642719; = p.E264A on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as rs771091108, COSV99427807; called by muse, varscan2
- MAGEL2 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 18/540 reads (3%) | SIFT tolerated, low confidence (0.1); catalogued as rs1216919340, COSV58568327; called by muse, mutect2
- MAN2C1 | c.3003T>A p.D1001E | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1394101995; called by muse, mutect2
- MAP1S | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 44/599 reads (7%) | catalogued as rs1213502630; called by muse, mutect2
- MAP3K10 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 54/452 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as rs759660870, COSV53423955; called by muse, varscan2
- MAP3K8 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs201540136, COSV53922411; called by muse, mutect2
- MAP3K9 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 29/313 reads (9%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.899); catalogued as COSV101173732; called by muse, mutect2
- MAP4K1 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 40/452 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.057); catalogued as rs756169111; called by muse, mutect2
- MCAM | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 49/425 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.285); catalogued as rs200795578, COSV50642169; called by muse, mutect2, varscan2
- MCM5 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 59/423 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs200021712, COSV53346220, COSV99331765; called by muse, mutect2, varscan2
- MCM5 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs749855231; called by muse, mutect2, varscan2
- MEGF10 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as rs1381176973, COSV57248817; called by muse, mutect2
- MEIS1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1262513073; called by muse, mutect2, varscan2
- MESP2 | c.1180G>T p.G394C | Missense Mutation (SNP) | VAF 34/310 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.671); catalogued as COSV59092411; called by muse, mutect2, varscan2
- METTL7B | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 27/277 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs776219569, COSV57693174; called by muse, mutect2, varscan2
- MEX3B | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 80/583 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs1393751691, COSV100313795; called by muse, mutect2, varscan2
- MFAP3 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 40/309 reads (13%) | catalogued as rs1271247189; called by muse, mutect2, varscan2
- MGAT3 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 52/481 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.68); catalogued as rs141535501; called by muse, mutect2, varscan2
- MGAT5B | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 51/461 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs769396088; called by muse, mutect2
- MMP21 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 56/415 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs17153524; called by muse, mutect2, varscan2
- MRGPRF | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 38/526 reads (7%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.977); catalogued as rs1225748904; called by muse, mutect2
- MRM1 | c.1062A>G p.*354Wext*60 | Nonstop Mutation (SNP) | VAF 37/337 reads (11%) | catalogued as rs1217090052; called by muse, mutect2, varscan2
- MRPL10 | c.167del p.P56Rfs*21 | Frame Shift Del (DEL) | VAF 38/345 reads (11%) | catalogued as rs1567950931, COSV51620933; called by mutect2, pindel, varscan2
- MRPS21 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 45/314 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as rs782778925, COSV58414586; called by muse, mutect2, varscan2
- MRPS36 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs376039866; called by muse, mutect2, varscan2
- MTHFSD | c.878C>T p.A293V (on ENST00000360900 / NM_001159377.2; = p.A292V on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/584 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV59803438; called by muse, mutect2
- MUC16 | c.16243G>A p.A5415T | Missense Mutation (SNP) | VAF 33/504 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs758745630, COSV67473688; called by muse, mutect2
- MUC17 | c.12844C>G p.Q4282E | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778500130, COSV100071322; called by muse, mutect2, varscan2
- MUC5B | c.15952G>A p.D5318N | Missense Mutation (SNP) | VAF 60/411 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780887119; called by muse, mutect2, varscan2
- MYBBP1A | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs763961344; called by muse, mutect2
- MYBPC1 | c.1673T>C p.M558T (on ENST00000550270 / NM_206820.2; = p.M583T on NM_002465.4) | Missense Mutation (SNP) | VAF 35/287 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.056); catalogued as rs767284171, COSV62258330; called by muse, mutect2, varscan2
- MYBPC2 | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as rs112900024; called by muse, mutect2, varscan2
- MYH7B | c.3956C>T p.A1319V | Missense Mutation (SNP) | VAF 25/333 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs374373234; called by muse, mutect2
- MYO7B | c.2219C>T p.A740V | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs1289806984; called by muse, mutect2
- MYRF | c.2264C>T p.P755L (on ENST00000278836 / NM_001127392.3; = p.P746L on NM_013279.4) | Missense Mutation (SNP) | VAF 48/301 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs745462025; called by muse, mutect2, varscan2
- NALCN | c.2204G>A p.R735Q | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs145128255; called by muse, mutect2, varscan2
- NAT1 | c.347G>A p.G116D | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.22); catalogued as COSV56985906; called by muse, mutect2, varscan2
- NCKAP5L | c.3832C>T p.R1278C | Missense Mutation (SNP) | VAF 42/589 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs534363616; called by muse, mutect2
- NCOA1 | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 25/303 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV99945202; called by muse, mutect2
- NEUROG1 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 36/640 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV100130687; called by muse, mutect2
- NFAM1 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753923440; called by muse, mutect2
- NGLY1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.174); catalogued as rs1023362606; called by muse, mutect2, varscan2
- NIPBL | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 36/329 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.586); catalogued as rs571300383; called by muse, mutect2, varscan2
- NKD1 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 38/372 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as rs764325270, COSV51692199; called by muse, mutect2
- NKIRAS2 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 47/390 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs782370487; called by muse, mutect2, varscan2
- NKX1-1 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 73/533 reads (14%) | SIFT tolerated, low confidence (0.27); catalogued as rs1251552066; called by muse, mutect2, varscan2
- NKX2-2 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 47/464 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1180786196, COSV65819325; called by muse, mutect2, varscan2
- NMI | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 65/366 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs189993135, COSV54637997; called by muse, mutect2, varscan2
- NOMO2 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 17/337 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as rs1321809598, COSV57918008; called by muse, mutect2
- NOTCH3 | c.3254T>C p.V1085A | Missense Mutation (SNP) | VAF 49/604 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV54636871; called by muse, mutect2
- NOTCH3 | c.2141G>A p.G714D | Missense Mutation (SNP) | VAF 36/346 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs763238354; called by muse, mutect2
- NPFFR1 | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 53/476 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53332519; called by muse, mutect2, varscan2
- NPHP1 | c.1114G>A p.G372S (on ENST00000393272 / NM_207181.4; = p.G373S on NM_000272.5) | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs1212929849; ClinVar: uncertain significance; called by muse, mutect2
- NPIPB15 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 40/499 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as rs752699064, COSV70436400; called by muse, mutect2
- NR0B1 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 88/343 reads (26%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs781487983; called by muse, mutect2, varscan2
- NR4A1 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750999884; called by muse, mutect2, varscan2
- NRROS | c.1352G>C p.G451A | Missense Mutation (SNP) | VAF 37/360 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs932793777; called by muse, mutect2, varscan2
- NRSN2 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs527597656, COSV66526990; called by muse, mutect2, varscan2
- NSD2 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 29/326 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs373161300; called by muse, mutect2
- NUCKS1 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 52/307 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as COSV65652919; called by muse, mutect2, varscan2
- NUP188 | c.1263G>T p.W421C | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1464197534; called by muse, mutect2, varscan2
- ODF3L2 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 42/535 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs753994574; called by muse, mutect2
- OR10G2 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 53/385 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as rs541165979, COSV73390434; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 36/295 reads (12%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2B11 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 23/345 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750162732, COSV59509298; called by muse, mutect2
- OR2T3 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 28/522 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV62083308; called by muse, mutect2
- OR4E1 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776253906; called by muse, mutect2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 36/338 reads (11%) | catalogued as rs748398423; called by mutect2, varscan2
- OR5L2 | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 33/413 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV65723506, COSV65724749; called by muse, mutect2
- OR5M10 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs1457498636; called by muse, mutect2
- OR5M8 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as rs760153338, COSV59117152; called by muse, varscan2
- OSBPL5 | c.2528C>T p.T843M | Missense Mutation (SNP) | VAF 46/376 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs541744828; called by muse, mutect2, varscan2
- OSR2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 44/633 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV52559561; called by muse, mutect2
- PAN2 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 46/427 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99228196; called by muse, mutect2, varscan2
- PAQR9 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 53/331 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV61418094; called by muse, mutect2, varscan2
- PARP1 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 56/387 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs369900729; called by muse, mutect2, varscan2
- PARP9 | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 20/230 reads (9%) | catalogued as rs756620968; called by muse, mutect2
- PATL1 | c.478dup p.Q160Pfs*6 | Frame Shift Ins (INS) | VAF 39/289 reads (13%) | catalogued as rs757903860; called by mutect2, varscan2
- PCDH10 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 59/456 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV52095480; called by muse, mutect2, varscan2
- PCDH10 | c.679del p.Q227Sfs*43 | Frame Shift Del (DEL) | VAF 26/220 reads (12%) | catalogued as COSV52090150; called by mutect2, pindel
- PCDHA12 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 45/436 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.056); catalogued as COSV56505834; called by muse, mutect2, varscan2
- PCDHA13 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 56/361 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs1345534362, COSV99169862; called by muse, mutect2, varscan2
- PCDHB14 | c.1837G>A p.G613R | Missense Mutation (SNP) | VAF 55/543 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs553823311, COSV99505795; called by muse, mutect2, varscan2
- PCDHB15 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 61/442 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs371639102; called by muse, mutect2, varscan2
- PCDHB3 | c.1702G>A p.G568S | Missense Mutation (SNP) | VAF 82/688 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.022); catalogued as rs782668326; called by muse, varscan2
- PCDHGA8 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 35/340 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.028); catalogued as rs758463890, COSV53988513; called by muse, mutect2, varscan2
- PCDHGB6 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 60/484 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.763); catalogued as COSV53959164; called by muse, mutect2, varscan2
- PCNX2 | c.6158G>A p.G2053D | Missense Mutation (SNP) | VAF 55/444 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV99269537; called by muse, mutect2, varscan2
- PDE6G | c.71G>T p.R24M | Missense Mutation (SNP) | VAF 54/416 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as rs770884576, COSV58507683; called by muse, mutect2, varscan2
- PDGFRA | c.2645G>A p.G882D | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57271760; called by muse, mutect2
- PDZD2 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV99223535; called by muse, mutect2, varscan2
- PDZD2 | c.4457C>T p.A1486V | Missense Mutation (SNP) | VAF 75/510 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs756008372; called by muse, mutect2, varscan2
- PELP1 | c.2392del p.L798Cfs*14 | Frame Shift Del (DEL) | VAF 29/203 reads (14%) | catalogued as rs752653446, COSV99342923; called by mutect2, pindel, varscan2
- PER1 | c.1138del p.L380Cfs*73 | Frame Shift Del (DEL) | VAF 58/350 reads (17%) | catalogued as rs1196410930; called by mutect2, pindel, varscan2
- PER2 | c.2572G>A p.V858M | Missense Mutation (SNP) | VAF 107/556 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); catalogued as rs79645972, COSV99612408; called by muse, mutect2, varscan2
- PHF21B | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 59/443 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV100503979; called by muse, mutect2, varscan2
- PHKB | c.1404G>T p.Q468H | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100068340; called by muse, mutect2, varscan2
- PIEZO1 | c.7396A>G p.I2466V | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs964611699; called by muse, mutect2, varscan2
- PIH1D1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.942); catalogued as rs961067131, COSV51806750; called by muse, mutect2, varscan2
- PITPNB | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs150364097; called by muse, mutect2, varscan2
- PKDREJ | c.3854C>T p.T1285M | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs371348205; called by muse, mutect2, varscan2
- PKN1 | c.2812G>A p.V938M | Missense Mutation (SNP) | VAF 48/366 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.08); catalogued as rs777305335; called by muse, mutect2, varscan2
- PLCB3 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 22/563 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54186985; called by muse, mutect2
- PLCL1 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 51/326 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV70825564; called by muse, mutect2, varscan2
- PLEC | c.10819G>A p.A3607T (on ENST00000322810 / NM_201380.4; = p.A3497T on NM_000445.5) | Missense Mutation (SNP) | VAF 36/810 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as rs377602333; ClinVar: uncertain significance; called by muse, mutect2
- PLEC | c.5129G>A p.S1710N (on ENST00000322810 / NM_201380.4; = p.S1600N on NM_000445.5) | Missense Mutation (SNP) | VAF 42/736 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1554701238; called by muse, mutect2
- PLEC | c.4615G>A p.V1539M (on ENST00000322810 / NM_201380.4; = p.V1429M on NM_000445.5) | Missense Mutation (SNP) | VAF 74/752 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs1554703829; called by muse, mutect2
- PLEKHG4 | c.2834G>A p.R945H | Missense Mutation (SNP) | VAF 44/416 reads (11%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.984); catalogued as rs754954657, COSV58574042; called by muse, mutect2, varscan2
- PLEKHG5 | c.970A>G p.R324G (on ENST00000400915 / NM_001042663.3; = p.R287G on NM_020631.6) | Missense Mutation (SNP) | VAF 38/487 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV61700141; called by muse, mutect2
- PLEKHG5 | c.774del p.T259Rfs*46 (on ENST00000400915 / NM_001042663.3; = p.T222Rfs*46 on NM_020631.6) | Frame Shift Del (DEL) | VAF 62/490 reads (13%) | catalogued as rs1224270266; called by mutect2, pindel, varscan2
- PLK3 | c.1928G>A p.R643H | Missense Mutation (SNP) | VAF 37/374 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs776334966, COSV59499136; called by muse, mutect2
- PNISR | c.806del p.K269Rfs*57 | Frame Shift Del (DEL) | VAF 46/348 reads (13%) | catalogued as rs779217645, COSV65078630; called by mutect2, pindel, varscan2
- PNPLA6 | c.1178del p.P393Rfs*10 (on ENST00000414982 / NM_001166111.2; = p.P345Rfs*10 on NM_006702.5) | Frame Shift Del (DEL) | VAF 53/448 reads (12%) | catalogued as COSV99652930; called by mutect2, pindel, varscan2
- POFUT1 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761191707, COSV99866946; called by muse, mutect2, varscan2
- POLD3 | c.861del p.A288Qfs*17 | Frame Shift Del (DEL) | VAF 42/342 reads (12%) | catalogued as rs1565122953; called by mutect2, pindel, varscan2
- POLE | c.5491_5492del p.L1831Afs*3 | Frame Shift Del (DEL) | VAF 52/347 reads (15%) | catalogued as rs878854883; called by pindel, varscan2
- POLE | c.4876C>T p.R1626C | Missense Mutation (SNP) | VAF 40/341 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753713315, COSV57683533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR3E | c.1027G>A p.G343S | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150257924; called by muse, mutect2, varscan2
- POM121C | c.3118A>G p.T1040A (on ENST00000607367; = p.T798A on NM_001099415.3) | Missense Mutation (SNP) | VAF 26/522 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.325); catalogued as rs782740641; called by muse, mutect2
- PPP1R32 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs146492932; called by muse, mutect2, varscan2
- PRDM8 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 42/754 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV60202651; called by muse, mutect2
- PROB1 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 77/488 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.031); catalogued as COSV56171438, COSV56171552; called by muse, mutect2, varscan2
- PROK1 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 45/316 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.658); catalogued as rs1276563561, COSV54765548; called by muse, mutect2, varscan2
- PRR12 | c.3637C>T p.R1213C (on ENST00000615927; = p.R2034C on NM_020719.3) | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs1182369022; called by muse, mutect2, varscan2
- PRR16 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65400637; called by muse, mutect2, varscan2
- PRR33 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 51/522 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1019595509; called by muse, mutect2, varscan2
- PRUNE1 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as CM1512555; called by muse, mutect2, varscan2
- PSMD6 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 28/340 reads (8%) | catalogued as rs993885519; called by muse, mutect2
- PTPRF | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV63443726; called by muse, mutect2, varscan2
- PTPRS | c.5150A>G p.Y1717C | Missense Mutation (SNP) | VAF 48/334 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260485320; called by muse, mutect2, varscan2
- PWWP2B | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 42/532 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs780057300, COSV100535706, COSV59452658; called by muse, mutect2
- R3HCC1 | c.1435C>T p.P479S (on ENST00000411463; = p.P439S on NM_001136108.3) | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1409985645; called by muse, mutect2, varscan2
- R3HDML | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 61/440 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1432931529, COSV99407289; called by muse, varscan2
- RAB5C | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60525554; called by muse, mutect2, varscan2
- RALYL | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 45/405 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs749865840, COSV72819608; called by muse, mutect2, varscan2
- RALYL | c.366C>T p.G122= | Splice Region (SNP) | VAF 21/230 reads (9%) | catalogued as rs182622234, COSV72818112; called by muse, mutect2, varscan2
- RAPGEF4 | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 68/322 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as rs199578267; called by muse, mutect2, varscan2
- RAVER1 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 72/643 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.61); catalogued as COSV99532283; called by muse, mutect2, varscan2
- RBP3 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 52/402 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs140357670; called by muse, mutect2, varscan2
- RCN1 | c.19G>C p.G7R | Missense Mutation (SNP) | VAF 48/396 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.519); catalogued as COSV50014844, COSV50014931; called by muse, mutect2, varscan2
- RERE | c.2897del p.P966Lfs*4 | Frame Shift Del (DEL) | VAF 51/375 reads (14%) | catalogued as rs5772316; called by mutect2, pindel, varscan2
- REXO5 | c.1157del p.K386Rfs*5 | Frame Shift Del (DEL) | VAF 26/190 reads (14%) | catalogued as rs34411848; called by mutect2, pindel, varscan2
- RFPL1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 54/422 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs753907886, COSV62978021; called by muse, varscan2
- RFXAP | c.359del p.G120Afs*18 | Frame Shift Del (DEL) | VAF 58/524 reads (11%) | catalogued as rs1224857205; called by mutect2, pindel, varscan2
- RGS19 | c.583del p.R195Afs*134 | Frame Shift Del (DEL) | VAF 48/371 reads (13%) | catalogued as COSV58659846; called by mutect2, pindel, varscan2
- RHBDF1 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 44/421 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV51955740; called by mutect2, varscan2
- RIMS2 | c.2903G>A p.R968Q (on ENST00000666250 / NM_001348490.2; = p.R776Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/281 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs376934485; called by muse, mutect2
- RIN1 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 31/438 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs758835427; called by muse, mutect2
- RIPK3 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.664); catalogued as COSV53476454; called by muse, mutect2, varscan2
- RNF146 | c.602C>T p.A201V (on ENST00000368314 / NM_001242850.2; = p.A200V on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/326 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.825); catalogued as rs764648313, COSV58933525; called by muse, mutect2, varscan2
- RNF17 | c.2552C>G p.T851S | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs559495991; called by muse, mutect2, varscan2
- RNF220 | c.269del p.P90Lfs*15 | Frame Shift Del (DEL) | VAF 37/375 reads (10%) | catalogued as COSV62407854; called by mutect2, pindel, varscan2
- RNF32 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs201228278; called by muse, mutect2, varscan2
- RNF38 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 35/427 reads (8%) | catalogued as COSV52393504; called by muse, mutect2
- RNF44 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs546486949; called by muse, mutect2
- RNPEPL1 | c.1864C>T p.R622W | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs193086300; called by muse, mutect2, varscan2
- ROS1 | c.4375G>A p.A1459T | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63852809; called by muse, mutect2, varscan2
- RPS6KA2 | c.1945G>A p.V649M | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs368787835; called by muse, mutect2, varscan2
- RPS6KA5 | c.2264C>T p.T755M | Missense Mutation (SNP) | VAF 40/366 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs759980356, COSV56223251; called by muse, mutect2
- RPTOR | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 46/373 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60804553, COSV60819799; called by muse, mutect2, varscan2
- RRAS | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 25/272 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs766259420; ClinVar: uncertain significance; called by muse, mutect2
- RSAD1 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 46/368 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs551405886; called by muse, mutect2, varscan2
- SALL1 | c.2792C>T p.P931L | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140924793, COSV51764357; called by muse, mutect2, varscan2
- SAMD9L | c.4547del p.N1516Mfs*10 | Frame Shift Del (DEL) | VAF 24/188 reads (13%) | catalogued as COSV59083791; called by mutect2, varscan2
- SCARF1 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 44/404 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1229804409, COSV53957683; called by muse, mutect2, varscan2
- SCN2B | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 49/430 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755650254; called by muse, mutect2, varscan2
- SCRN1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs141518349; called by muse, mutect2, varscan2
- SEMA3E | c.1570A>C p.S524R | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV57085885; called by muse, mutect2, varscan2
- SEMA3F | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 47/397 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs763853986; called by muse, varscan2
- SEMA3F | c.2294G>A p.R765Q | Missense Mutation (SNP) | VAF 71/438 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs775992407; called by muse, mutect2, varscan2
- SEMA6D | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs145652546, COSV100317034; called by muse, mutect2
- SENP6 | c.1198C>G p.P400A | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs754346919, COSV100519583; called by muse, mutect2
- SERINC4 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.523); catalogued as rs753212840; called by muse, mutect2, varscan2
- SERPINE1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 24/255 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs145904727; called by muse, mutect2, varscan2
- SFI1 | c.2528G>A p.R843Q (on ENST00000400288 / NM_001007467.3; = p.R812Q on NM_014775.4) | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs751059390; called by muse, mutect2, varscan2
- SFXN2 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 46/372 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs201929596, COSV100882728, COSV64011826; called by muse, mutect2, varscan2
- SH3GLB1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs747420023, COSV65280547; called by muse, mutect2, varscan2
- SH3TC1 | c.2279G>A p.S760N | Missense Mutation (SNP) | VAF 52/550 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as rs755155779, COSV55283247; called by muse, mutect2
- SHE | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 59/507 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs751927506, COSV59071105; called by muse, mutect2, varscan2
- SHISA3 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 29/379 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs866477983; called by muse, mutect2
- SIGLEC5 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 43/346 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as rs765090595, COSV55778632; called by muse, varscan2
- SIX5 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 65/546 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs1382510435; called by muse, mutect2, varscan2
- SIX6 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 35/404 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.82); catalogued as rs753263476, COSV59802847; called by muse, mutect2
- SKI | c.1189C>A p.L397I | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.304); catalogued as COSV66012918; called by muse, mutect2, varscan2
- SLC12A5 | c.498G>A p.T166= (on ENST00000454036 / NM_001134771.2; = p.T143= on NM_020708.5) | Splice Region (SNP) | VAF 22/253 reads (9%) | catalogued as rs749462257, COSV54792977; called by muse, mutect2, varscan2
- SLC13A2 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 42/431 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781925291; called by muse, mutect2, varscan2
- SLC13A4 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.961); catalogued as rs148680605; called by muse, mutect2, varscan2
- SLC19A1 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 53/477 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753215575; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 36/287 reads (13%) | catalogued as rs749849908; called by mutect2, varscan2
- SLC24A1 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs956792845, COSV99978191; called by muse, mutect2
- SLC25A30 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 33/301 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770621512, COSV60433512; called by muse, mutect2, varscan2
- SLC26A1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 65/459 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs369294755; called by muse, mutect2, varscan2
- SLC35C1 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 49/373 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs748793953, COSV100029354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC39A10 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs146699959; called by muse, mutect2, varscan2
- SLC45A4 | c.1033dup p.R345Pfs*32 (on ENST00000517878 / NM_001286646.2; = p.R294Pfs*32 on NM_001080431.2) | Frame Shift Ins (INS) | VAF 64/583 reads (11%) | catalogued as rs768004505; called by mutect2, pindel
- SLC6A1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 22/303 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); catalogued as rs778818301, COSV99822614; called by muse, mutect2
- SLC6A6 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 50/318 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs761829964, COSV62648350; called by muse, mutect2, varscan2
- SLC7A8 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs761696643, COSV57554478; called by muse, mutect2, varscan2
- SLC8A1 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 42/335 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317243583, COSV100247582, COSV60473723; called by muse, mutect2, varscan2
- SLC8B1 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 49/307 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs960986075, COSV52528266; called by muse, mutect2, varscan2
- SLIT2 | c.4270G>T p.G1424W | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56566280; called by muse, mutect2, varscan2
- SLTM | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 45/300 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.813); catalogued as rs144086273; called by muse, varscan2
- SMARCAD1 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs1440635478, COSV100759022; called by muse, mutect2
- SMIM36 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 17/316 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as rs1026408318; called by muse, mutect2
- SMPD3 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 45/407 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762901829, COSV54714455; called by muse, mutect2, varscan2
- SNX32 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 44/359 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs368432434; called by muse, mutect2, varscan2
- SOBP | c.1379T>C p.I460T | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs1433750983; called by muse, mutect2
- SORBS2 | c.3086C>T p.P1029L (on ENST00000284776 / NM_021069.5; = p.P595L on NM_003603.6) | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs1482132914; called by muse, mutect2
- SORBS3 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 64/553 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.216); catalogued as rs751559982, COSV53552813; called by muse, mutect2, varscan2
- SORCS3 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs989139495, COSV63803335; called by muse, mutect2, varscan2
- SOWAHA | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 56/441 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as rs138513605; called by muse, mutect2, varscan2
- SOX11 | c.1148del p.G383Afs*39 | Frame Shift Del (DEL) | VAF 57/512 reads (11%) | catalogued as rs1553328038; called by mutect2, pindel, varscan2
- SOX30 | c.1813G>A p.G605R | Missense Mutation (SNP) | VAF 40/376 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746507800; called by muse, mutect2, varscan2
- SOX7 | c.463dup p.A155Gfs*10 | Frame Shift Ins (INS) | VAF 66/515 reads (13%) | catalogued as rs769092194; called by mutect2, pindel, varscan2
- SPAG17 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs772685293, COSV60453868; called by muse, mutect2, varscan2
- SPAG5 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 42/337 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs747402791; called by muse, mutect2, varscan2
- SPINK7 | c.87del p.V30Wfs*42 | Frame Shift Del (DEL) | VAF 21/206 reads (10%) | catalogued as rs747884448; called by mutect2, pindel, varscan2
- SPSB4 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 67/547 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs763040261; called by muse, mutect2, varscan2
- SRRM5 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 54/420 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs533532185, COSV100334813; called by muse, mutect2, varscan2
- SSC5D | c.1396dup p.Q466Pfs*20 | Frame Shift Ins (INS) | VAF 44/330 reads (13%) | catalogued as rs1323431546; called by mutect2, pindel, varscan2
- SSU72P8 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 29/374 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs527981837; called by muse, mutect2
- STARD13 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 15/285 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.386); catalogued as rs1173429347; called by muse, mutect2
- STAT6 | c.841dup p.Q281Pfs*92 | Frame Shift Ins (INS) | VAF 44/307 reads (14%) | catalogued as rs767674545; called by mutect2, varscan2
- STBD1 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 37/538 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs114722810, COSV99421491; called by muse, mutect2
- STOML3 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs533210440, COSV65510570; called by muse, mutect2, varscan2
- STPG1 | c.842G>A p.R281H (on ENST00000337248 / NM_001199013.2; = p.R234H on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/462 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs747319327; called by muse, mutect2
- STYX | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1422791149, COSV63462498; called by muse, varscan2
- STYXL2 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1290225945, COSV54811337; called by muse, mutect2
- SULF1 | c.223dup p.A75Gfs*48 | Frame Shift Ins (INS) | VAF 46/343 reads (13%) | catalogued as rs747316268; called by mutect2, varscan2
- SYNE1 | c.11414G>A p.R3805Q (on ENST00000367255 / NM_182961.4; = p.R3790Q on NM_033071.3) | Missense Mutation (SNP) | VAF 39/375 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754270893, COSV54921171, COSV55010734; called by muse, mutect2, varscan2
- SYT1 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 25/332 reads (8%) | catalogued as rs7972950; called by muse, mutect2
- TADA3 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.94); catalogued as rs759684453; called by muse, mutect2, varscan2
- TAFA5 | c.250G>A p.A84T (on ENST00000402357 / NM_001082967.3; = p.A77T on NM_015381.7) | Missense Mutation (SNP) | VAF 46/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1423621130, COSV60969464; called by muse, mutect2, varscan2
- TAGAP | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs751645528, COSV57850520; called by muse, mutect2, varscan2
- TAL1 | c.851T>C p.V284A | Missense Mutation (SNP) | VAF 50/453 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs778566200; called by muse, mutect2, varscan2
- TANC2 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs183360210; called by muse, mutect2, varscan2
- TBC1D10B | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 56/445 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as rs776458764, COSV59768631; called by muse, mutect2, varscan2
- TBX3 | c.1412G>A p.R471H (on ENST00000257566 / NM_016569.4; = p.R451H on NM_005996.4) | Missense Mutation (SNP) | VAF 70/622 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.474); catalogued as rs1438073122; called by muse, mutect2, varscan2
- TC2N | c.600_602del p.S201del | In Frame Del (DEL) | VAF 33/281 reads (12%) | catalogued as rs778997308; called by pindel, varscan2
- TCHP | c.522del p.K174Nfs*26 | Frame Shift Del (DEL) | VAF 26/182 reads (14%) | catalogued as rs763438715; called by mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 30/254 reads (12%) | catalogued as rs763321097; called by mutect2, varscan2
- TECPR1 | c.3121G>A p.A1041T | Missense Mutation (SNP) | VAF 47/321 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs760164335; called by muse, mutect2, varscan2
- TENM3 | c.2218A>G p.I740V | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs764567102; called by muse, mutect2
- TENM3 | c.7498G>A p.V2500I | Missense Mutation (SNP) | VAF 59/443 reads (13%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.939); catalogued as rs755588039, COSV104434191; called by muse, mutect2, varscan2
- TENT5B | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 49/409 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201078551; called by muse, mutect2, varscan2
- TERF2 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 37/272 reads (14%) | catalogued as rs771872522; called by muse, mutect2, varscan2
- TFR2 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 52/408 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746407340, CM136281; called by muse, mutect2, varscan2
- TG | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756627185; called by muse, varscan2
- TGFB1I1 | c.548C>T p.P183L (on ENST00000394863 / NM_001042454.3; = p.P166L on NM_015927.4) | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs757123886, COSV62358774; called by muse, mutect2, varscan2
- TGFB2 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs989462091, COSV65108810; called by muse, varscan2
- THSD7B | c.215A>G p.D72G | Missense Mutation (SNP) | VAF 29/334 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV55687685; called by muse, mutect2
- TIAM2 | c.4852G>A p.E1618K (on ENST00000529824; = p.E1589K on NM_012454.3) | Missense Mutation (SNP) | VAF 40/350 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs767085875, COSV51640254; called by muse, mutect2, varscan2
- TICRR | c.5524A>C p.S1842R | Missense Mutation (SNP) | VAF 45/363 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99176014; called by muse, mutect2, varscan2
- TIE1 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 44/441 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs748212442, COSV100992153, COSV104424150; called by muse, mutect2, varscan2
- TIE1 | c.2032G>A p.V678I | Missense Mutation (SNP) | VAF 34/520 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs895434484, COSV100992253; called by muse, mutect2
- TIGD6 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs766485002; called by muse, mutect2
- TLCD2 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 53/610 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs868219602; called by muse, mutect2
- TLN1 | c.2666G>A p.R889Q | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs540431162; called by muse, mutect2, varscan2
- TMEM117 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56914199; called by muse, mutect2, varscan2
- TMEM132E | c.2810C>T p.A937V (on ENST00000321639; = p.A1027V on NM_001304438.2) | Missense Mutation (SNP) | VAF 61/588 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs1378003351; called by muse, mutect2, varscan2
- TMEM18 | c.233G>T p.R78I | Missense Mutation (SNP) | VAF 26/315 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99806110; called by muse, mutect2
- TMEM198 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 42/399 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV99525310; called by muse, mutect2, varscan2
- TMEM222 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 48/380 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.948); catalogued as rs765278796; called by muse, mutect2, varscan2
- TMEM269 | c.24del p.C9Afs*18 | Frame Shift Del (DEL) | VAF 42/337 reads (12%) | catalogued as rs1224221227; called by mutect2, pindel, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 22/159 reads (14%) | catalogued as rs770800449; called by mutect2, varscan2
- TNN | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 65/410 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs151048294, COSV53426279; called by muse, mutect2, varscan2
- TNS2 | c.2323G>A p.E775K (on ENST00000314250 / NM_170754.4; = p.E785K on NM_015319.2) | Missense Mutation (SNP) | VAF 48/443 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs373588998; called by muse, mutect2, varscan2
- TOGARAM1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 53/380 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV100752978; called by muse, mutect2, varscan2
- TONSL | c.3494A>G p.Q1165R | Missense Mutation (SNP) | VAF 51/424 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV68048402; called by muse, mutect2, varscan2
- TPSG1 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 67/546 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1334300624; called by muse, mutect2, varscan2
- TRAF7 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 40/344 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1313697003, COSV58219344; called by muse, mutect2, varscan2
- TRARG1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 46/407 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs374210765; called by muse, mutect2, varscan2
- TRHDE | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 51/390 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as rs1368408252; called by muse, varscan2
- TRPM4 | c.3553G>A p.V1185I | Missense Mutation (SNP) | VAF 57/420 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); catalogued as rs758731104, COSV53270467; called by muse, mutect2, varscan2
- TRPM5 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 46/396 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as rs139404126; called by muse, mutect2, varscan2
- TSPAN10 | c.457C>G p.P153A (on ENST00000574882 / NM_001290212.1; = p.P115A on NM_031945.4) | Missense Mutation (SNP) | VAF 112/646 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as rs753180923, COSV60773117; called by muse, mutect2, varscan2
- TSPYL5 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 38/661 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.27); catalogued as rs1428017957; called by muse, mutect2
- TSR3 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 50/406 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs760237348; called by muse, mutect2, varscan2
- TSSK4 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs1370985892; called by muse, mutect2, varscan2
- TTLL5 | c.3098T>G p.L1033R | Missense Mutation (SNP) | VAF 31/354 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1489208821; called by muse, mutect2
- TTN | c.86549G>A p.R28850H (on ENST00000591111; = p.R21426H on NM_003319.4) | Missense Mutation (SNP) | VAF 62/307 reads (20%) | PolyPhen probably damaging (0.998); catalogued as rs765777852; called by muse, mutect2, varscan2
- TTN | c.70232G>A p.R23411H (on ENST00000591111; = p.R15987H on NM_003319.4) | Missense Mutation (SNP) | VAF 34/245 reads (14%) | PolyPhen probably damaging (0.917); catalogued as rs542720402, COSV59961982; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.64585G>A p.E21529K (on ENST00000591111; = p.E14105K on NM_003319.4) | Missense Mutation (SNP) | VAF 43/461 reads (9%) | PolyPhen benign (0.311); catalogued as rs1334543067, COSV60276327; ClinVar: likely benign; called by muse, mutect2
- TUBB6 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 30/492 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as rs772400475, COSV52314843; called by muse, mutect2
- TULP1 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 40/305 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100004142; called by muse, mutect2, varscan2
- TUSC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 34/353 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs1165905233; called by muse, mutect2, varscan2
- TYRO3 | c.725G>C p.S242T | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.058); catalogued as COSV99777521; called by muse, mutect2
- UBE2L6 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54702344, COSV54702407; called by muse, mutect2, varscan2
- UBE2W | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 25/298 reads (8%) | catalogued as rs1373683191, COSV62480140; called by muse, mutect2
- UBQLN4 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as rs1052018568, COSV64145825; called by muse, mutect2, varscan2
- UBR3 | c.4692del p.F1564Lfs*45 | Frame Shift Del (DEL) | VAF 19/182 reads (10%) | catalogued as COSV55855220; called by mutect2, pindel, varscan2
- UBR4 | c.8966G>A p.R2989Q | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.06); catalogued as rs201716368; called by muse, mutect2, varscan2
- UBR7 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 46/292 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs764896805; called by muse, varscan2
- UBTF | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207491061, COSV57186978; called by muse, mutect2, varscan2
- UFL1 | c.255A>G p.V85= | Splice Region (SNP) | VAF 22/152 reads (14%) | catalogued as rs1191498341; called by muse, mutect2, varscan2
- UGDH | c.214del p.S72Lfs*18 | Frame Shift Del (DEL) | VAF 18/148 reads (12%) | catalogued as rs765734647, COSV57097233; called by mutect2, varscan2
- UMOD | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 44/599 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV104405230; called by muse, mutect2
- UNC5B | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 43/366 reads (12%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.572); catalogued as rs538475514; called by muse, mutect2, varscan2
- UNC79 | c.4478del p.K1493Sfs*12 (on ENST00000393151 / NM_001346218.2; = p.K1316Sfs*12 on NM_020818.5) | Frame Shift Del (DEL) | VAF 47/311 reads (15%) | catalogued as rs760213136; called by mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 56/236 reads (24%) | catalogued as rs767420916; called by mutect2, varscan2
- USP32 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.771); catalogued as rs779796906; called by muse, mutect2, varscan2
- USP35 | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 50/526 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs749222931; called by muse, mutect2
- USP40 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 76/398 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.732); catalogued as rs369754257; called by muse, varscan2
- USP50 | c.718G>A p.A240T (on ENST00000616326; = p.A231T on NM_203494.5) | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776670490, COSV73213974; called by muse, mutect2, varscan2
- UTF1 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 60/568 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV58679019; called by muse, mutect2, varscan2
- UTP20 | c.392del p.L131* | Frame Shift Del (DEL) | VAF 42/305 reads (14%) | catalogued as rs761528888; called by mutect2, varscan2
- UTP25 | c.832del p.L278Sfs*7 | Frame Shift Del (DEL) | VAF 38/341 reads (11%) | catalogued as rs750214623; called by mutect2, pindel, varscan2
- VASP | c.551del p.P184Hfs*84 | Frame Shift Del (DEL) | VAF 24/162 reads (15%) | catalogued as rs762759767; called by mutect2, varscan2
- VAV2 | c.1778C>T p.A593V (on ENST00000371850 / NM_001134398.2; = p.A583V on NM_003371.4) | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.934); catalogued as rs1351582845, COSV64081771; called by muse, mutect2
- VIPAS39 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754342872, COSV58942319; called by muse, mutect2
- VXN | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 59/472 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs774421011; called by muse, mutect2, varscan2
- WDR5 | c.648dup p.V217Rfs*42 | Frame Shift Ins (INS) | VAF 24/260 reads (9%) | catalogued as rs780890680; called by mutect2, varscan2
- WDR54 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 53/341 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779254262; called by muse, mutect2, varscan2
- WDR6 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 44/383 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as rs535256576; called by muse, mutect2, varscan2
- WDTC1 | c.1467T>C p.G489= (on ENST00000319394 / NM_001276252.2; = p.G488= on NM_015023.5) | Splice Region (SNP) | VAF 12/244 reads (5%) | catalogued as rs1438267582; called by muse, mutect2
- WFDC3 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as rs372743246; called by muse, mutect2, varscan2
- WIPI2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 54/383 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs780899323, COSV56591392; called by muse, mutect2, varscan2
- XIRP2 | c.9503G>A p.G3168D (on ENST00000628543; = p.G3343D on NM_152381.6) | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV54740427, COSV99738875; called by muse, mutect2, varscan2
- XRRA1 | c.2222G>A p.R741Q | Missense Mutation (SNP) | VAF 55/441 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.462); catalogued as rs753120857, COSV104394983; called by muse, mutect2, varscan2
- XYLT1 | c.2324G>T p.G775V | Missense Mutation (SNP) | VAF 56/409 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54489121; called by muse, mutect2, varscan2
- YAP1 | c.34G>C p.A12P | Missense Mutation (SNP) | VAF 44/404 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs927540361; called by mutect2, varscan2
- YWHAH | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV50708630; called by muse, mutect2, varscan2
- ZAP70 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 44/400 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1246320051; called by muse, mutect2, varscan2
- ZBED6 | c.2110G>A p.V704M | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.866); catalogued as rs768256437; called by muse, mutect2
- ZBTB39 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 48/402 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs773932686; called by muse, varscan2
- ZBTB42 | c.730A>G p.S244G | Missense Mutation (SNP) | VAF 61/406 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1278637334; called by muse, mutect2, varscan2
- ZFP57 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 75/542 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs755918943, COSV100971987; called by muse, mutect2, varscan2
- ZFR | c.2725G>A p.A909T | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1260896724; called by muse, mutect2, varscan2
- ZFYVE26 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs779962087, COSV61324121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZGRF1 | c.3985T>A p.S1329T | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); catalogued as rs772061401; called by muse, mutect2, varscan2
- ZNF232 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 39/458 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs768813214; called by muse, mutect2
- ZNF317 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 21/387 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs529554441; called by muse, mutect2
- ZNF423 | c.877C>T p.R293C (on ENST00000563137 / NM_001379286.1; = p.R285C on NM_015069.4) | Missense Mutation (SNP) | VAF 36/454 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs201388998, COSV52192029, COSV99284095; called by muse, mutect2
- ZNF433 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 30/393 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs769243125; called by muse, mutect2
- ZNF469 | c.9419C>T p.A3140V (on ENST00000437464; = p.A3168V on NM_001367624.2) | Missense Mutation (SNP) | VAF 61/511 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs1485800441; called by muse, mutect2, varscan2
- ZNF48 | c.745del p.R249Dfs*43 | Frame Shift Del (DEL) | VAF 60/505 reads (12%) | catalogued as rs780189754; called by mutect2, pindel, varscan2
- ZNF516 | c.2699C>G p.A900G | Missense Mutation (SNP) | VAF 73/513 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs1231884564, COSV71587093; called by muse, mutect2, varscan2
- ZNF518A | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.549); catalogued as rs782330269, COSV100283286; called by muse, mutect2
- ZNF521 | c.1963del p.T655Lfs*10 | Frame Shift Del (DEL) | VAF 41/325 reads (13%) | catalogued as COSV64132044; called by mutect2, pindel, varscan2
- ZNF536 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 68/457 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs373259584, COSV62821921; called by muse, mutect2, varscan2
- ZNF560 | c.1774C>T p.R592* | Nonsense Mutation (SNP) | VAF 37/347 reads (11%) | catalogued as rs746257684; called by muse, mutect2, varscan2
- ZNF638 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 32/427 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs202139397, COSV52482379; called by muse, mutect2
- ZNF662 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100066658; called by muse, mutect2, varscan2
- ZNF687 | c.3235C>T p.R1079C | Missense Mutation (SNP) | VAF 31/374 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs1298060342, COSV99650154; called by muse, mutect2
- ZNF716 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 25/265 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs782303620; called by muse, varscan2
- ZNF835 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 41/396 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs1178083297, COSV101606370; called by muse, mutect2, varscan2
- ZNF865 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 68/546 reads (12%) | SIFT tolerated (0.73); catalogued as rs1487653204; called by muse, varscan2
- AADACL2 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 31/374 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2
- ABCA12 | c.206C>A p.P69Q | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ACAP2 | c.1583dup p.F529Vfs*4 | Frame Shift Ins (INS) | VAF 32/221 reads (14%) | called by mutect2, varscan2
- ADAM29 | c.1123dup p.W375Lfs*13 | Frame Shift Ins (INS) | VAF 38/416 reads (9%) | called by mutect2, pindel
- ADAMTSL3 | c.1006dup p.Y336Lfs*12 | Frame Shift Ins (INS) | VAF 42/302 reads (14%) | called by mutect2, pindel, varscan2
- ADAMTSL4 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 63/435 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADCY10 | c.4295G>T p.R1432I | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADCY5 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 70/492 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ADGRE1 | c.2017C>T p.H673Y | Missense Mutation (SNP) | VAF 32/311 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADGRF3 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 16/359 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); called by muse, mutect2
- ADGRF4 | c.1174T>C p.S392P | Missense Mutation (SNP) | VAF 24/347 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ADH1C | c.173T>C p.L58P | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.823); called by muse, mutect2
- AGBL2 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AHNAK | c.15463del p.I5155* | Frame Shift Del (DEL) | VAF 38/396 reads (10%) | called by mutect2, pindel
- AHNAK | c.6091G>A p.D2031N | Missense Mutation (SNP) | VAF 28/504 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.046); called by muse, mutect2
- AKAP6 | c.4521dup p.S1508Ifs*5 | Frame Shift Ins (INS) | VAF 37/312 reads (12%) | called by mutect2, pindel, varscan2
- AL135905.2 | c.102C>A p.C34* | Nonsense Mutation (SNP) | VAF 28/346 reads (8%) | called by muse, mutect2
- AL391650.1 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); called by muse, mutect2
- AL451007.3 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 52/570 reads (9%) | called by muse, mutect2
- ALDH16A1 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 49/356 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALKBH7 | c.518_519del p.Y173* | Frame Shift Del (DEL) | VAF 40/259 reads (15%) | called by mutect2, pindel, varscan2
- ALS2 | c.3442_3444del p.P1148del | In Frame Del (DEL) | VAF 30/299 reads (10%) | called by mutect2, pindel, varscan2
- ALX4 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 22/553 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.054); called by muse, mutect2
- AMER1 | c.519del p.F173Lfs*36 | Frame Shift Del (DEL) | VAF 58/256 reads (23%) | called by mutect2, pindel, varscan2
- AMER3 | c.1669del p.A557Rfs*127 | Frame Shift Del (DEL) | VAF 47/426 reads (11%) | called by mutect2, varscan2
- AMHR2 | c.1562G>T p.C521F | Missense Mutation (SNP) | VAF 56/455 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD11 | c.6016G>T p.G2006W | Missense Mutation (SNP) | VAF 26/670 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2
- ANKRD26 | c.527del p.N176Tfs*12 | Frame Shift Del (DEL) | VAF 19/205 reads (9%) | called by mutect2, pindel, varscan2
- ANKRD50 | c.2897dup p.L966Ffs*11 | Frame Shift Ins (INS) | VAF 41/347 reads (12%) | called by mutect2, pindel, varscan2
- ANKRD6 | c.1943C>T p.A648V (on ENST00000339746 / NM_001242809.2; = p.A643V on NM_014942.4) | Missense Mutation (SNP) | VAF 26/424 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.079); called by muse, mutect2
- ANO1 | c.2222T>G p.L741R | Missense Mutation (SNP) | VAF 45/311 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO8 | c.1705del p.E569Kfs*46 | Frame Shift Del (DEL) | VAF 42/279 reads (15%) | called by mutect2, pindel, varscan2
- ANO8 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 61/542 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- AP2A1 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 45/396 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- APOA1 | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 30/478 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.063); called by muse, mutect2
- APOB | c.4922A>G p.H1641R | Missense Mutation (SNP) | VAF 15/350 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARC | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 33/534 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.199); called by muse, mutect2
- ARHGAP23 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 45/724 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- ARHGEF17 | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 43/402 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ARHGEF3 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 35/199 reads (18%) | called by muse, mutect2, varscan2
- ARHGEF33 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 52/425 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ARID1B | c.3812del p.G1271Efs*2 | Frame Shift Del (DEL) | VAF 40/238 reads (17%) | called by mutect2, pindel, varscan2
- ARMC6 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 31/304 reads (10%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ASTN1 | c.2920A>G p.T974A | Missense Mutation (SNP) | VAF 33/321 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- ASTN2 | c.3935G>A p.S1312N (on ENST00000313400 / NM_001365069.1; = p.S1261N on NM_014010.5) | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- ATAD3B | c.436G>A p.A146T (on ENST00000308647; = p.A252T on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ATP10A | c.4178C>A p.P1393H | Missense Mutation (SNP) | VAF 61/584 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); called by muse, mutect2
- ATP8A2 | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATP8B3 | c.1234T>C p.Y412H | Missense Mutation (SNP) | VAF 33/448 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2
- ATRN | c.2863A>G p.M955V | Missense Mutation (SNP) | VAF 55/398 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AXIN2 | c.1795del p.A599Pfs*90 | Frame Shift Del (DEL) | VAF 85/486 reads (17%) | called by mutect2, pindel, varscan2
- B3GNT9 | c.1027dup p.Q343Pfs*18 | Frame Shift Ins (INS) | VAF 67/445 reads (15%) | called by mutect2, pindel, varscan2
- BARHL2 | c.718del p.S240Pfs*18 | Frame Shift Del (DEL) | VAF 36/283 reads (13%) | called by mutect2, varscan2
- BCAN | c.2089G>T p.G697C | Missense Mutation (SNP) | VAF 43/408 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BCL11B | c.1237C>T p.P413S (on ENST00000357195 / NM_001282237.2; = p.P342S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/588 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.113); called by muse, mutect2
- BCL9 | c.4071G>A p.M1357I | Missense Mutation (SNP) | VAF 28/537 reads (5%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.775); called by muse, mutect2
- BCL9L | c.3685C>T p.P1229S | Missense Mutation (SNP) | VAF 72/591 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- BEND5 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
1,078 further variants in this file (598 protein-altering or splice-affecting, 424 silent, 56 other) are not listed here.
